Somatic mutation profile of tumor specimen C3L-00144-01 (aliquot CPT0001960012) from CPTAC case C3L-00144, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 58.8 years (21,487 days).
Specimen C3L-00144-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7819fdb5-0060-45ed-b493-ff55b99990bf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00144-31 (Blood Derived Normal), aliquot CPT0003980002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a66abf1-a5da-4cfa-97e3-ad6032d1f652

The open-access MAF lists 1,997 somatic variants for this specimen: 1,371 protein-altering or splice-affecting, 385 silent, 241 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,170, Silent 385, Intron 110, Nonsense Mutation 94, RNA 47, Frame Shift Del 38, Splice Site 34, 5'UTR 27, 3'UTR 27, 5'Flank 19, Splice Region 14, Frame Shift Ins 14.

Variants (750 of 1,997; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCN1A | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 41/263 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs121917918, CM044039, COSV100320807; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.461G>T p.G154V | Missense Mutation (SNP) | VAF 73/247 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs762846821, CM951223, COSV52667239, COSV52783646, COSV53625267; called by muse, mutect2, varscan2
- ABCB10 | c.1320G>T p.W440C | Missense Mutation (SNP) | VAF 52/404 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV60620478; called by muse, mutect2, varscan2
- ABCF3 | c.1651G>T p.A551S | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.061); catalogued as rs775301972; called by muse, mutect2, varscan2
- ABCG8 | c.1186G>T p.V396L | Missense Mutation (SNP) | VAF 146/613 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs145992603, COSV55397649; called by muse, mutect2, varscan2
- ACOT11 | c.1715G>T p.R572L | Missense Mutation (SNP) | VAF 12/66 reads (18%) | catalogued as rs377475734; called by muse, mutect2, varscan2
- ACSM2B | c.1528A>G p.I510V | Missense Mutation (SNP) | VAF 23/204 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766749039; called by muse, varscan2
- ACTRT1 | c.553G>A p.G185R | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64419090; called by muse, mutect2, varscan2
- ADAD1 | c.148G>T p.A50S | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.468); catalogued as rs1159070252; called by muse, mutect2, varscan2
- ADAMTS12 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61272347; called by muse, mutect2, varscan2
- ADAMTS19 | c.901G>T p.G301C | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV50748824; called by muse, mutect2, varscan2
- ADAMTS20 | c.4889G>T p.R1630L | Missense Mutation (SNP) | VAF 39/208 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as COSV67130572, COSV67132104, COSV67137399; called by muse, mutect2, varscan2
- ADAMTS20 | c.3724G>T p.D1242Y | Missense Mutation (SNP) | VAF 41/257 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV101166183; called by muse, mutect2, varscan2
- ADCK1 | c.772G>C p.E258Q | Missense Mutation (SNP) | VAF 51/193 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV53079064; called by muse, mutect2, varscan2
- ADCY4 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs140776899, COSV60256546; called by muse, mutect2, varscan2
- ADGRB2 | c.1886G>T p.R629L | Missense Mutation (SNP) | VAF 15/169 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.866); catalogued as COSV57074009; called by muse, mutect2
- AFP | c.526C>A p.P176T | Missense Mutation (SNP) | VAF 69/295 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as rs772839127; called by muse, mutect2, varscan2
- AIG1 | c.364G>T p.D122Y | Missense Mutation (SNP) | VAF 98/285 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1316310371; called by muse, mutect2, varscan2
- ALPK1 | c.3415G>T p.V1139L | Missense Mutation (SNP) | VAF 47/211 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1480021893; called by muse, mutect2, varscan2
- AMZ1 | c.1065G>C p.E355D | Missense Mutation (SNP) | VAF 50/230 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.237); catalogued as rs200135799; called by muse, mutect2, varscan2
- ANAPC11 | c.134C>A p.P45Q | Missense Mutation (SNP) | VAF 46/179 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs761412036; called by muse, mutect2, varscan2
- ANKRD18A | c.1309G>T p.V437L | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1181981638; called by muse, mutect2
- AOX1 | c.1615C>A p.P539T | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV65979831; called by muse, mutect2
- APOB | c.12004G>T p.A4002S | Missense Mutation (SNP) | VAF 72/318 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs760313331; called by muse, mutect2, varscan2
- APOB | c.7369C>A p.L2457M | Missense Mutation (SNP) | VAF 103/563 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51942374; called by muse, mutect2, varscan2
- APOB | c.3511G>T p.E1171* | Nonsense Mutation (SNP) | VAF 90/508 reads (18%) | catalogued as COSV51945398, COSV51958163; called by muse, varscan2
- ARHGEF6 | c.346G>T p.E116* | Nonsense Mutation (SNP) | VAF 64/173 reads (37%) | catalogued as COSV51687711; called by muse, mutect2, varscan2
- ARID1A | c.4468G>T p.E1490* | Nonsense Mutation (SNP) | VAF 77/322 reads (24%) | catalogued as COSV61374200, COSV61375315; called by muse, mutect2, varscan2
- ARPP21 | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.088); catalogued as COSV51794116; called by muse, mutect2
- ARPP21 | c.1823G>T p.G608V | Missense Mutation (SNP) | VAF 30/274 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.682); catalogued as COSV51795477; called by muse, mutect2, varscan2
- ASL | c.599G>T p.G200V | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59188037; called by muse, mutect2, varscan2
- ASXL2 | c.2368A>C p.T790P | Missense Mutation (SNP) | VAF 36/203 reads (18%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs749134751; called by muse, mutect2, varscan2
- ATP13A2 | c.1306+8G>A | Splice Region (SNP) | VAF 101/428 reads (24%) | catalogued as COSV58702000; called by muse, mutect2, varscan2
- ATP6V1B1 | c.785+1G>T p.X262_splice | Splice Site (SNP) | VAF 64/454 reads (14%) | catalogued as CS991327, COSV52268252, COSV99314101; called by muse, mutect2, varscan2
- ATP7B | c.1271C>A p.A424D | Missense Mutation (SNP) | VAF 55/335 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV54443403; called by muse, mutect2, varscan2
- ATRNL1 | c.1804G>T p.V602L | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs781952348; called by muse, varscan2
- AVPR1A | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 76/360 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV54546529; called by muse, mutect2, varscan2
- AVPR1A | c.387C>A p.H129Q | Missense Mutation (SNP) | VAF 27/171 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs563622430; called by muse, mutect2, varscan2
- AVPR2 | c.495del p.F166Sfs*46 | Frame Shift Del (DEL) | VAF 125/305 reads (41%) | catalogued as CM025909; called by mutect2, pindel, varscan2
- BAG6 | c.307G>T p.G103W | Missense Mutation (SNP) | VAF 95/211 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV52990648; called by muse, mutect2, varscan2
- BAHD1 | c.1271C>T p.S424L | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs1415687083, COSV101346765; called by muse, mutect2, varscan2
- BCAN | c.1906G>A p.A636T | Missense Mutation (SNP) | VAF 58/245 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs546794419; called by muse, mutect2, varscan2
- BLK | c.820G>T p.G274* | Nonsense Mutation (SNP) | VAF 69/356 reads (19%) | catalogued as COSV52050491; called by muse, mutect2, varscan2
- BOD1L1 | c.5627G>T p.R1876I | Missense Mutation (SNP) | VAF 43/210 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV50067594; called by muse, mutect2, varscan2
- BRI3BP | c.509G>T p.C170F | Missense Mutation (SNP) | VAF 50/418 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV58296987; called by mutect2, varscan2
- BRINP3 | c.1909G>T p.G637C | Missense Mutation (SNP) | VAF 38/323 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); catalogued as COSV66516533, COSV66525950; called by muse, mutect2, varscan2
- BSND | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 20/163 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as CM013299; called by muse, varscan2
- C10orf71 | c.4226G>A p.G1409E | Missense Mutation (SNP) | VAF 31/233 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs569147976; called by muse, mutect2, varscan2
- C22orf15 | c.400C>A p.R134S | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs747372262; called by muse, mutect2, varscan2
- C5orf49 | c.412G>T p.E138* | Nonsense Mutation (SNP) | VAF 70/319 reads (22%) | catalogued as COSV57892490, COSV57908378; called by muse, mutect2, varscan2
- C6orf118 | c.964G>C p.G322R | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.083); catalogued as COSV57820649; called by muse, mutect2
- CACNA1B | c.6869G>A p.R2290H | Missense Mutation (SNP) | VAF 30/312 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.861); catalogued as rs76756995, COSV53154042; called by muse, mutect2
- CACNA1I | c.2598G>T p.Q866H | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); catalogued as COSV60813392; called by muse, mutect2, varscan2
- CACNA2D1 | c.2669C>T p.S890L (on ENST00000356253 / NM_001366867.1; = p.S878L on NM_000722.4) | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV100665229; called by muse, varscan2
- CACNG4 | c.758C>A p.S253* | Nonsense Mutation (SNP) | VAF 67/258 reads (26%) | catalogued as COSV50924610; called by muse, mutect2, varscan2
- CADM3 | c.471C>G p.S157R (on ENST00000368125 / NM_001127173.3; = p.S191R on NM_021189.5) | Missense Mutation (SNP) | VAF 43/187 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV63685798; called by muse, mutect2, varscan2
- CALN1 | c.644G>A p.R215Q (on ENST00000329008 / NM_001017440.3; = p.R257Q on NM_031468.4) | Missense Mutation (SNP) | VAF 19/179 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs370771019, COSV61142530; called by muse, mutect2, varscan2
- CARD6 | c.1494del p.Q499Kfs*9 | Frame Shift Del (DEL) | VAF 57/335 reads (17%) | catalogued as COSV54564843; called by mutect2, pindel, varscan2
- CCDC141 | c.4118G>T p.R1373M | Missense Mutation (SNP) | VAF 78/320 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV55369842; called by muse, mutect2, varscan2
- CCDC85A | c.941C>A p.P314Q | Missense Mutation (SNP) | VAF 58/306 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV68153423; called by muse, mutect2, varscan2
- CCT8L2 | c.398G>T p.R133L | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.097); catalogued as rs149623775, COSV100742670; called by muse, mutect2, varscan2
- CDH10 | c.424C>A p.P142T | Missense Mutation (SNP) | VAF 136/453 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779300580, COSV52597547; called by muse, mutect2, varscan2
- CDH18 | c.2001C>A p.D667E | Missense Mutation (SNP) | VAF 153/463 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56948513; called by muse, mutect2, varscan2
- CDH18 | c.1787G>T p.R596L | Missense Mutation (SNP) | VAF 133/561 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV56901300, COSV56916324; called by muse, varscan2
- CDH19 | c.144C>A p.N48K | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs759627014, COSV100051553, COSV50972116; called by muse, mutect2, varscan2
- CDK11A | c.1819G>A p.V607M (on ENST00000378633 / NM_001313896.2; = p.V604M on NM_024011.4) | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs753808941; called by muse, mutect2, varscan2
- CENPQ | c.440G>T p.R147L | Missense Mutation (SNP) | VAF 60/268 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.148); catalogued as COSV59920891; called by muse, mutect2, varscan2
- CETN1 | c.441C>G p.D147E | Missense Mutation (SNP) | VAF 71/172 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.077); catalogued as rs1054408089; called by muse, mutect2, varscan2
- CFAP91 | c.347G>T p.R116L | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.025); catalogued as rs760911940, COSV56344323; called by muse, mutect2, varscan2
- CFHR2 | c.91G>T p.G31* | Nonsense Mutation (SNP) | VAF 23/197 reads (12%) | catalogued as COSV66382446; called by muse, mutect2, varscan2
- CHL1 | c.1264C>G p.R422G (on ENST00000397491 / NM_001253387.1; = p.R438G on NM_006614.4) | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs771129031, COSV56597553, COSV56606581; called by muse, mutect2, varscan2
- CHST1 | c.286G>T p.V96F | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145528990; called by muse, mutect2, varscan2
- CLEC4G | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.106); catalogued as COSV100183620; called by muse, mutect2, varscan2
- CLVS1 | c.82G>T p.A28S | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.076); catalogued as COSV100369250; called by muse, mutect2, varscan2
- CNBD1 | c.610C>A p.L204I | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.89); catalogued as rs762132294; called by muse, mutect2, varscan2
- CNGA4 | c.339G>T p.W113C | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.102); catalogued as COSV66006798; called by muse, mutect2
- CNTNAP2 | c.131C>G p.P44R | Missense Mutation (SNP) | VAF 41/320 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV62168210, COSV62265810; called by muse, mutect2, varscan2
- CNTNAP4 | c.2413C>G p.H805D | Missense Mutation (SNP) | VAF 49/232 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56695783; called by muse, mutect2, varscan2
- COL14A1 | c.3464G>T p.R1155M | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.621); catalogued as COSV52861031; called by muse, mutect2, varscan2
- COL17A1 | c.937C>A p.Q313K | Missense Mutation (SNP) | VAF 47/202 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV100792959; called by muse, mutect2, varscan2
- COL1A2 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 122/446 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1206388800, CM090272, COSV51958812; called by muse, mutect2, varscan2
- COL3A1 | c.1871G>T p.G624V | Missense Mutation (SNP) | VAF 55/268 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1553508463, COSV100483620; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A1 | c.2089G>T p.G697C | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65671661; called by muse, mutect2, varscan2
- COL6A5 | c.4517G>A p.G1506E | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55205674, COSV55216020; called by muse, mutect2, varscan2
- COL6A5 | c.4609G>A p.G1537S | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1411828064; called by muse, mutect2, varscan2
- COL8A1 | c.1579C>T p.P527S | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.669); catalogued as rs1243037670; called by muse, mutect2, varscan2
- CPLANE1 | c.9578G>A p.W3193* | Nonsense Mutation (SNP) | VAF 55/131 reads (42%) | catalogued as COSV99951501; called by muse, mutect2, varscan2
- CPS1 | c.3490G>C p.V1164L | Missense Mutation (SNP) | VAF 18/486 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99242328; called by muse, mutect2
- CSMD1 | c.8320G>T p.V2774L (on ENST00000520002; = p.V2773L on NM_033225.6) | Missense Mutation (SNP) | VAF 31/206 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.042); catalogued as COSV59298405, COSV59302575; called by muse, mutect2, varscan2
- CSMD3 | c.5189G>T p.G1730V (on ENST00000297405 / NM_001363185.1; = p.G1626V on NM_052900.3) | Missense Mutation (SNP) | VAF 29/181 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52260783; called by muse, varscan2
- CTNND2 | c.1367G>T p.S456I | Missense Mutation (SNP) | VAF 39/260 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as COSV58908549; called by muse, mutect2, varscan2
- CWH43 | c.1760G>C p.G587A | Missense Mutation (SNP) | VAF 13/165 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV56943741; called by muse, mutect2
- DBF4 | c.1327G>T p.D443Y | Missense Mutation (SNP) | VAF 44/186 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); catalogued as rs1377090555; called by muse, varscan2
- DEFB119 | c.68G>T p.R23L | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.321); catalogued as COSV53620422, COSV53620448; called by muse, mutect2, varscan2
- DEPDC5 | c.1421G>T p.R474L | Missense Mutation (SNP) | VAF 51/236 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); catalogued as rs1349979537; called by muse, mutect2, varscan2
- DGAT1 | c.1232C>T p.S411L | Missense Mutation (SNP) | VAF 20/189 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs573410614, COSV60046776; called by muse, mutect2, varscan2
- DGKI | c.2377C>A p.Q793K | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.146); catalogued as COSV55947934, COSV55957104; called by muse, mutect2, varscan2
- DHX34 | c.1375G>T p.G459* | Nonsense Mutation (SNP) | VAF 32/255 reads (13%) | catalogued as rs765082398, COSV100169203; called by muse, mutect2, varscan2
- DHX38 | c.3671G>A p.R1224H | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs369140795, COSV51698160; called by muse, mutect2, varscan2
- DNAH14 | c.5758C>T p.P1920S (on ENST00000445597; = p.P2460S on NM_001367479.1) | Missense Mutation (SNP) | VAF 26/206 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as COSV99071037; called by muse, mutect2, varscan2
- DNAH3 | c.4754C>A p.T1585N | Missense Mutation (SNP) | VAF 15/182 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1038070234; called by muse, mutect2
- DNAH8 | c.10495C>T p.R3499C | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758179326, COSV59469603; called by muse, mutect2, varscan2
- DNAH9 | c.1978A>T p.T660S | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV52335545; called by muse, varscan2
- DPPA2 | c.734C>G p.A245G | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.078); catalogued as COSV72118315; called by muse, mutect2, varscan2
- DPYS | c.1099G>A p.G367S | Missense Mutation (SNP) | VAF 40/231 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100037170; called by muse, mutect2, varscan2
- DSP | c.8554G>T p.A2852S | Missense Mutation (SNP) | VAF 55/140 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.758); catalogued as COSV60939195; called by muse, mutect2, varscan2
- DTNA | c.1858G>T p.A620S | Missense Mutation (SNP) | VAF 104/320 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs566869682; called by muse, mutect2, varscan2
- DUSP10 | c.395G>T p.G132V | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.419); catalogued as rs1266524759, COSV100100664; called by muse, mutect2, varscan2
- DYSF | c.1634G>T p.G545V | Missense Mutation (SNP) | VAF 93/561 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99244505; called by muse, mutect2, varscan2
- EIF4G1 | c.1387G>C p.E463Q (on ENST00000346169 / NM_198241.3; = p.E267Q on NM_004953.5) | Missense Mutation (SNP) | VAF 42/253 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as COSV59995009; called by muse, mutect2, varscan2
- ELAVL1 | c.808G>T p.V270F | Missense Mutation (SNP) | VAF 124/362 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60967626; called by muse, mutect2
- ENC1 | c.202A>G p.S68G | Missense Mutation (SNP) | VAF 72/198 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56630244; called by muse, mutect2, varscan2
- EPHA5 | c.265G>T p.V89L | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.018); catalogued as COSV56635889; called by muse, varscan2
- EPHA6 | c.2698G>T p.V900F (on ENST00000389672 / NM_001080448.3; = p.V292F on NM_173655.4) | Missense Mutation (SNP) | VAF 58/241 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101064849; called by muse, mutect2, varscan2
- ERCC2 | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 38/210 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.026); catalogued as rs1445063129; called by muse, mutect2, varscan2
- ERICH3 | c.3299C>A p.A1100E | Missense Mutation (SNP) | VAF 36/254 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV58604279; called by muse, varscan2
- ETS2 | c.962C>T p.S321F | Missense Mutation (SNP) | VAF 40/552 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.107); catalogued as COSV62874335; called by muse, mutect2
- EVC | c.2233G>T p.G745W | Missense Mutation (SNP) | VAF 50/238 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752249506; called by muse, varscan2
- EXPH5 | c.2647G>C p.A883P | Missense Mutation (SNP) | VAF 36/224 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.394); catalogued as rs774746550; called by muse, mutect2, varscan2
- F5 | c.3832C>G p.P1278A | Missense Mutation (SNP) | VAF 133/550 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs374687606; called by muse, varscan2
- FAM110C | c.610C>T p.L204F | Missense Mutation (SNP) | VAF 55/340 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as rs1015142024; called by muse, mutect2, varscan2
- FAM135B | c.4061T>A p.V1354D | Missense Mutation (SNP) | VAF 68/317 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as COSV99426853; called by muse, mutect2, varscan2
- FAM47B | c.931C>A p.P311T | Missense Mutation (SNP) | VAF 64/176 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs1318292953; called by muse, mutect2, varscan2
- FAM53B | c.343C>A p.R115S | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV55101540; called by muse, mutect2, varscan2
- FANCB | c.1384G>T p.E462* | Nonsense Mutation (SNP) | VAF 13/67 reads (19%) | catalogued as COSV100146471; called by muse, mutect2, varscan2
- FBRSL1 | c.1554C>A p.F518L | Missense Mutation (SNP) | VAF 12/236 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as COSV55516850; called by muse, mutect2
- FCN2 | c.380G>T p.R127L | Missense Mutation (SNP) | VAF 32/295 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs575801515, COSV52475918, COSV52476122; called by muse, mutect2, varscan2
- FCRLA | c.469C>A p.Q157K (on ENST00000367959; = p.Q134K on NM_032738.4) | Missense Mutation (SNP) | VAF 17/196 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs376314134; called by muse, mutect2
- FEZF2 | c.678C>A p.F226L | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV51862121; called by muse, mutect2, varscan2
- FGA | c.113G>T p.R38M | Missense Mutation (SNP) | VAF 110/429 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57401544; called by muse, mutect2, varscan2
- FGD6 | c.3733C>T p.R1245W | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781251883; called by muse, mutect2, varscan2
- FGF14 | c.193G>T p.D65Y | Missense Mutation (SNP) | VAF 38/363 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as rs1199591646, COSV65948545; called by muse, mutect2, varscan2
- FILIP1L | c.1414C>A p.L472I (on ENST00000354552 / NM_182909.3; = p.L232I on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/251 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV100496186; called by muse, mutect2
- FLG | c.8207G>T p.G2736V | Missense Mutation (SNP) | VAF 30/192 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs775902916, COSV100910313; called by mutect2, varscan2
- FLNB | c.6725A>G p.D2242G | Missense Mutation (SNP) | VAF 45/333 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.2); catalogued as rs770170754; called by muse, mutect2, varscan2
- FOXG1 | c.1306G>C p.A436P | Missense Mutation (SNP) | VAF 81/389 reads (21%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.415); catalogued as COSV57395141; called by muse, mutect2, varscan2
- FTCD | c.862_864del p.K288del | In Frame Del (DEL) | VAF 32/395 reads (8%) | catalogued as rs1321726682; called by mutect2, pindel
- FZD9 | c.1195A>G p.T399A | Missense Mutation (SNP) | VAF 29/228 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.678); catalogued as rs1172909758; called by muse, mutect2, varscan2
- GABRA4 | c.338C>A p.P113H | Missense Mutation (SNP) | VAF 28/223 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs148039186; called by muse, mutect2, varscan2
- GABRB1 | c.1242C>A p.Y414* | Nonsense Mutation (SNP) | VAF 25/135 reads (19%) | catalogued as COSV54979613, COSV99780315; called by muse, mutect2, varscan2
- GAK | c.1067G>A p.S356N | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs1426958076; called by muse, mutect2, varscan2
- GCNT3 | c.428T>C p.I143T | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.669); catalogued as rs762250026; called by muse, mutect2, varscan2
- GEM | c.803G>T p.R268L | Missense Mutation (SNP) | VAF 65/340 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV52597934; called by muse, mutect2, varscan2
- GFAP | c.1408G>T p.D470Y (on ENST00000253408 / NM_001363846.2; = p.D430Y on NM_002055.5) | Missense Mutation (SNP) | VAF 114/432 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV53653943; called by muse, mutect2, varscan2
- GIMAP4 | c.463C>T p.R155W | Missense Mutation (SNP) | VAF 30/282 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.271); catalogued as rs200682848; called by muse, mutect2, varscan2
- GLI1 | c.821del p.G274Afs*6 | Frame Shift Del (DEL) | VAF 22/132 reads (17%) | catalogued as rs759448855, COSV99954330; called by mutect2, varscan2
- GLI1 | c.2251C>A p.L751M | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.986); catalogued as COSV57364860, COSV99953633; called by muse, mutect2, varscan2
- GOLGA3 | c.2932A>T p.M978L | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as rs1198900104; called by muse, mutect2, varscan2
- GPR158 | c.2644G>T p.A882S | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66269338; called by muse, varscan2
- GPRIN3 | c.1894C>A p.P632T | Missense Mutation (SNP) | VAF 50/198 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1222219233; called by muse, mutect2, varscan2
- GRIA4 | c.1843C>A p.P615T | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99230242; called by muse, varscan2
- GRIK2 | c.1774C>G p.P592A | Missense Mutation (SNP) | VAF 63/234 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.042); catalogued as COSV59724596, COSV59743395; called by muse, varscan2
- GRIN2B | c.1962G>T p.M654I | Missense Mutation (SNP) | VAF 53/392 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV101663234; called by muse, varscan2
- GRIN3A | c.391G>T p.A131S | Missense Mutation (SNP) | VAF 45/377 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as rs1197993004; called by muse, mutect2, varscan2
- GRIPAP1 | c.1924C>T p.R642C | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1468936421; called by muse, mutect2, varscan2
- GRM3 | c.1114G>A p.V372I | Missense Mutation (SNP) | VAF 98/333 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as rs776686228, COSV100862421; called by muse, mutect2, varscan2
- GTDC1 | c.1000G>T p.A334S | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.046); catalogued as COSV53996910; called by muse, mutect2, varscan2
- HECW1 | c.2992G>C p.E998Q | Missense Mutation (SNP) | VAF 90/461 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.12); catalogued as COSV67828851; called by muse, mutect2, varscan2
- HGD | c.1141G>T p.A381S | Missense Mutation (SNP) | VAF 66/386 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as rs1270932950; called by mutect2, varscan2
- HIF3A | c.731G>A p.R244H (on ENST00000377670 / NM_152795.4; = p.R175H on NM_022462.4) | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs573123002, COSV99356162; called by muse, mutect2, varscan2
- HOXA6 | c.389G>T p.R130L | Missense Mutation (SNP) | VAF 80/236 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.24); catalogued as COSV56074702; called by muse, mutect2, varscan2
- HPSE2 | c.824A>T p.N275I | Missense Mutation (SNP) | VAF 100/407 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65202973; called by muse, mutect2, varscan2
- HRNR | c.2290G>T p.G764C | Missense Mutation (SNP) | VAF 70/338 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.737); catalogued as rs750750547, COSV64256732; called by muse, mutect2, varscan2
- HSD17B1 | c.170C>A p.P57Q | Missense Mutation (SNP) | VAF 95/293 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs61738807, COSV56798617; called by muse, mutect2, varscan2
- HSPA4L | c.995G>T p.R332L | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0.142); catalogued as rs558328437; called by muse, mutect2, varscan2
- IFIT3 | c.1281G>T p.Q427H | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.294); catalogued as COSV51080675; called by muse, mutect2, varscan2
- IGHV3-20 | c.138C>A p.F46L | Missense Mutation (SNP) | VAF 78/296 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.603); catalogued as rs782747493; called by muse, varscan2
- IGKV1D-16 | c.331C>A p.Q111K | Missense Mutation (SNP) | VAF 62/393 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs777668997; called by muse, mutect2, varscan2
- IKZF2 | c.32C>T p.T11M | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as rs370533090, COSV59577891; called by muse, mutect2, varscan2
- IL16 | c.1828G>T p.D610Y | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV57264099; called by muse, mutect2, varscan2
- IL17RA | c.608G>T p.W203L | Missense Mutation (SNP) | VAF 144/601 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60052970; called by muse, varscan2
- IL1RL1 | c.550A>G p.I184V | Missense Mutation (SNP) | VAF 55/199 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.038); catalogued as rs1470130458; called by muse, mutect2, varscan2
- IRF2BP1 | c.1462G>C p.G488R | Missense Mutation (SNP) | VAF 57/182 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.114); catalogued as COSV56194265; called by muse, mutect2, varscan2
- ISLR2 | c.352G>T p.D118Y | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62303161; called by muse, mutect2, varscan2
- ITIH4 | c.2420G>A p.R807Q | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.098); catalogued as rs141527900; called by muse, mutect2, varscan2
- KANSL1L | c.1012G>T p.G338C | Missense Mutation (SNP) | VAF 44/290 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55996589; called by muse, mutect2, varscan2
- KCNJ6 | c.1034G>T p.G345V | Missense Mutation (SNP) | VAF 67/298 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55714580; called by muse, mutect2, varscan2
- KCNV2 | c.106C>A p.R36S | Missense Mutation (SNP) | VAF 71/208 reads (34%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.068); catalogued as COSV66055828; called by muse, mutect2, varscan2
- KCTD3 | c.1352G>T p.R451L | Missense Mutation (SNP) | VAF 77/269 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52065441; called by muse, mutect2, varscan2
- KDM3B | c.1740G>T p.K580N | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.121); catalogued as COSV58695708; called by muse, mutect2, varscan2
- KIAA1549L | c.1882+4C>T | Splice Region (SNP) | VAF 20/88 reads (23%) | catalogued as COSV99684126; called by muse, varscan2
- KIAA1671 | c.1003G>T p.A335S | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as rs913064531; called by muse, mutect2, varscan2
- KIAA1755 | c.1930C>A p.Q644K | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT tolerated (0.93); PolyPhen benign (0.096); catalogued as COSV54074914, COSV54075706; called by muse, mutect2, varscan2
- KIFC2 | c.1961G>T p.R654L | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs866584575; called by muse, mutect2, varscan2
- KLF7 | c.437G>T p.R146L | Missense Mutation (SNP) | VAF 147/375 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as rs747043061; called by muse, mutect2, varscan2
- KNL1 | c.6689C>T p.S2230L (on ENST00000346991 / NM_170589.5; = p.S2204L on NM_144508.5) | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61152096; called by muse, varscan2
- KPRP | c.898C>A p.R300S | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); catalogued as COSV64220932; called by muse, mutect2, varscan2
- KPRP | c.1183C>T p.P395S | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64221373; called by muse, mutect2, varscan2
- KRT13 | c.1043C>T p.T348M | Missense Mutation (SNP) | VAF 99/558 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs759178223, COSV55839611; called by muse, mutect2, varscan2
- KRT2 | c.862G>T p.D288Y | Missense Mutation (SNP) | VAF 75/431 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1364295320; called by muse, varscan2
- KRT6C | c.1243C>A p.R415S | Missense Mutation (SNP) | VAF 78/481 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52876737; called by muse, mutect2, varscan2
- KRTAP10-4 | c.548C>A p.S183Y | Missense Mutation (SNP) | VAF 112/853 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.056); catalogued as COSV100555888; called by muse, varscan2
- KRTAP6-3 | c.231C>A p.D77E | Missense Mutation (SNP) | VAF 44/270 reads (16%) | PolyPhen benign (0.035); catalogued as COSV66963102; called by muse, mutect2, varscan2
- KRTAP9-2 | c.491G>T p.C164F | Missense Mutation (SNP) | VAF 62/226 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as COSV100893259; called by muse, mutect2
- LAMB2 | c.47G>T p.W16L | Missense Mutation (SNP) | VAF 27/263 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.202); catalogued as COSV59738060; called by muse, mutect2
- LARP4B | c.1297G>T p.E433* | Nonsense Mutation (SNP) | VAF 26/312 reads (8%) | catalogued as COSV60221316; called by muse, mutect2
- LDB3 | c.1703G>T p.R568L | Missense Mutation (SNP) | VAF 15/171 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.597); catalogued as COSV99555693; called by muse, mutect2
- LILRA1 | c.766G>T p.V256F | Missense Mutation (SNP) | VAF 50/264 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as rs763672344; called by muse, varscan2
- LILRA5 | c.371G>T p.W124L | Missense Mutation (SNP) | VAF 89/367 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.931); catalogued as rs1261148405; called by muse, mutect2, varscan2
- LMNTD2 | c.217C>A p.L73M | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54241613; called by muse, mutect2
- LPIN2 | c.2279G>T p.R760L | Missense Mutation (SNP) | VAF 63/200 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as COSV55240764; called by muse, mutect2, varscan2
- LRPAP1 | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 25/159 reads (16%) | catalogued as rs1468703329; called by muse, mutect2, varscan2
- MACF1 | c.19622G>C p.R6541P (on ENST00000372915; = p.R4586P on NM_012090.5) | Missense Mutation (SNP) | VAF 40/365 reads (11%) | catalogued as COSV57114717; called by muse, mutect2, varscan2
- MAG | c.774C>A p.S258R | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.495); catalogued as rs760841895; called by muse, mutect2, varscan2
- MAGEB6 | c.816T>A p.S272R | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.863); catalogued as COSV66872848; called by muse, mutect2, varscan2
- MAGI3 | c.1942G>T p.V648L | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs772683176; called by muse, mutect2
- MALRD1 | c.5665G>T p.E1889* | Nonsense Mutation (SNP) | VAF 34/159 reads (21%) | catalogued as COSV101035447; called by muse, mutect2, varscan2
- MARK2 | c.1478G>T p.S493I (on ENST00000402010 / NM_001039469.2; = p.S492I on NM_004954.5) | Missense Mutation (SNP) | VAF 58/231 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs762439455; called by muse, mutect2, varscan2
- MARK4 | c.1553del p.P518Rfs*102 | Frame Shift Del (DEL) | VAF 93/322 reads (29%) | catalogued as COSV53469249; called by mutect2, pindel, varscan2
- MAST1 | c.2717G>T p.G906V | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.034); catalogued as rs1431982580; called by muse, mutect2, varscan2
- MEGF10 | c.1255G>T p.A419S | Missense Mutation (SNP) | VAF 73/245 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as rs1275181352; called by muse, mutect2, varscan2
- MGAM2 | c.868C>A p.P290T | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV72176230; called by muse, varscan2
- MGAT4C | c.529G>T p.E177* | Nonsense Mutation (SNP) | VAF 29/153 reads (19%) | catalogued as COSV59831507; called by muse, mutect2, varscan2
- MMP23B | c.110T>A p.L37Q | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.852); catalogued as rs1283366598; called by muse, mutect2, varscan2
- MSANTD4 | c.983G>C p.R328P | Missense Mutation (SNP) | VAF 45/172 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.381); catalogued as COSV57285627; called by muse, mutect2, varscan2
- MSR1 | c.638G>T p.S213I | Missense Mutation (SNP) | VAF 20/244 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.216); catalogued as rs201900187; called by muse, mutect2
- MSX2 | c.440C>A p.T147K | Missense Mutation (SNP) | VAF 64/216 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53326576; called by muse, mutect2, varscan2
- MTA2 | c.1541G>T p.R514L | Missense Mutation (SNP) | VAF 49/266 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV53471220; called by muse, mutect2, varscan2
- MUC16 | c.35579C>A p.T11860K | Missense Mutation (SNP) | VAF 44/416 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.68); catalogued as rs781184049; called by muse, mutect2, varscan2
- MUC16 | c.30715G>A p.E10239K | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.281); catalogued as COSV67485550; called by muse, mutect2, varscan2
- MUC16 | c.24008C>A p.S8003* | Nonsense Mutation (SNP) | VAF 19/139 reads (14%) | catalogued as COSV67450042; called by muse, mutect2, varscan2
- MUC16 | c.21548C>A p.A7183E | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.012); catalogued as rs370133928, COSV67463370; called by muse, mutect2, varscan2
- MUC19 | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.608); catalogued as COSV70100582; called by muse, mutect2, varscan2
- MUC2 | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 34/398 reads (9%) | SIFT deleterious (0.04); catalogued as rs1021172202; called by muse, mutect2
- MUC4 | c.14329C>A p.H4777N (on ENST00000463781 / NM_018406.7; = p.H541N on NM_004532.6) | Missense Mutation (SNP) | VAF 30/236 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.078); catalogued as rs1264206713; called by muse, mutect2, varscan2
- MYH4 | c.3001A>G p.K1001E | Missense Mutation (SNP) | VAF 82/372 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as rs1472684397; called by muse, mutect2
- MYL10 | c.200G>T p.R67L | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs1184788588; called by muse, mutect2, varscan2
- NALCN | c.3582G>C p.P1194= | Splice Region (SNP) | VAF 19/166 reads (11%) | catalogued as COSV51951314; called by muse, mutect2, varscan2
- NAV3 | c.1705A>G p.I569V | Missense Mutation (SNP) | VAF 41/180 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs376491041; called by muse, mutect2, varscan2
- NBEA | c.1585G>T p.A529S | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.968); catalogued as COSV59800035; called by muse, mutect2, varscan2
- NEK10 | c.2940G>T p.E980D | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as COSV99835489; called by muse, mutect2, varscan2
- NELL1 | c.2158-2A>G p.X720_splice | Splice Site (SNP) | VAF 19/84 reads (23%) | catalogued as rs771413640; called by muse, varscan2
- NKX2-4 | c.850G>T p.G284C | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1251329353; called by muse, mutect2, varscan2
- NLRP8 | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 27/184 reads (15%) | catalogued as COSV52583328; called by muse, mutect2, varscan2
- NLRP8 | c.1342C>A p.Q448K | Missense Mutation (SNP) | VAF 69/235 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as COSV99405414; called by muse, mutect2, varscan2
- NPAS3 | c.187C>A p.R63S (on ENST00000356141 / NM_001164749.2; = p.R33S on NM_022123.3) | Missense Mutation (SNP) | VAF 50/163 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100385342, COSV58094126; called by muse, mutect2, varscan2
- NPFFR2 | c.703G>T p.V235F | Missense Mutation (SNP) | VAF 49/206 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1459895468; called by muse, mutect2, varscan2
- NSUN5 | c.953T>C p.L318P | Missense Mutation (SNP) | VAF 30/231 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV53091191; called by muse, mutect2, varscan2
- OBSCN | c.4178G>T p.S1393I | Missense Mutation (SNP) | VAF 55/515 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV52791866, COSV99478507; called by muse, mutect2, varscan2
- OGFR | c.497G>T p.R166L | Missense Mutation (SNP) | VAF 64/387 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs748501417; called by muse, mutect2, varscan2
- OLFML1 | c.7G>C p.V3L | Missense Mutation (SNP) | VAF 31/160 reads (19%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as COSV61402329; called by muse, mutect2, varscan2
- OR10C1 | c.725G>T p.C242F (on ENST00000622521; = p.C240F on NM_013941.3) | Missense Mutation (SNP) | VAF 135/342 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV65823496; called by muse, mutect2, varscan2
- OR10H1 | c.839C>A p.T280K | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV58472898; called by muse, mutect2, varscan2
- OR13D1 | c.896C>G p.T299S | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV100598651; called by muse, mutect2, varscan2
- OR13F1 | c.311C>A p.S104Y | Missense Mutation (SNP) | VAF 33/286 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58251766; called by muse, mutect2, varscan2
- OR2A25 | c.295C>A p.Q99K | Missense Mutation (SNP) | VAF 67/468 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101376408; called by muse, mutect2, varscan2
- OR2F1 | c.528C>A p.H176Q | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101231294; called by muse, mutect2, varscan2
- OR2M7 | c.271T>A p.S91T | Missense Mutation (SNP) | VAF 18/189 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as COSV58740145; called by muse, mutect2
- OR2T1 | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.052); catalogued as rs140525966; called by muse, mutect2, varscan2
- OR4C3 | c.33C>A p.F11L | Missense Mutation (SNP) | VAF 53/216 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV60583624, COSV60585910; called by muse, mutect2, varscan2
- OR4N2 | c.634C>A p.L212M | Missense Mutation (SNP) | VAF 20/356 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV60052372; called by muse, mutect2
- OR4N2 | c.635T>A p.L212Q | Missense Mutation (SNP) | VAF 18/360 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV60050882; called by muse, mutect2
- OR51M1 | c.143T>A p.M48K | Missense Mutation (SNP) | VAF 85/385 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as rs186800052; called by muse, mutect2, varscan2
- OR52I1 | c.597C>A p.S199R | Missense Mutation (SNP) | VAF 61/266 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV56168672; called by muse, mutect2, varscan2
- OR52J3 | c.539A>G p.Y180C | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs765933660; called by muse, mutect2, varscan2
- OR5D18 | c.305T>A p.F102Y | Missense Mutation (SNP) | VAF 45/325 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as COSV61737819; called by muse, mutect2, varscan2
- OR6C1 | c.588G>C p.M196I | Missense Mutation (SNP) | VAF 55/233 reads (24%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.006); catalogued as rs1426162646, COSV101110568; called by muse, mutect2, varscan2
- OR8B8 | c.158C>A p.S53Y | Missense Mutation (SNP) | VAF 85/339 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as COSV60143711; called by muse, mutect2, varscan2
- OR8H3 | c.668C>G p.S223C | Missense Mutation (SNP) | VAF 40/204 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.229); catalogued as rs769797689, COSV57908525, COSV57908776; called by muse, mutect2, varscan2
- ORMDL3 | c.461G>T p.*154Lext*39 | Nonstop Mutation (SNP) | VAF 15/80 reads (19%) | catalogued as COSV100401521, COSV58346185; called by muse, mutect2, varscan2
- OTOF | c.3362C>T p.P1121L (on ENST00000272371 / NM_194248.3; = p.P374L on NM_004802.4) | Missense Mutation (SNP) | VAF 89/446 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as rs779205233; called by muse, mutect2, varscan2
- OTOG | c.2508C>A p.D836E | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.97); PolyPhen probably damaging (0.988); catalogued as rs1198667667; called by muse, mutect2, varscan2
- OTOG | c.6287G>T p.R2096L | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.063); catalogued as rs1395557172, COSV100695333; called by muse, mutect2
- OXCT2 | c.704G>T p.C235F | Missense Mutation (SNP) | VAF 43/244 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV59594758; called by muse, mutect2, varscan2
- PADI1 | c.1874T>A p.L625Q | Missense Mutation (SNP) | VAF 37/305 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100968640; called by muse, mutect2, varscan2
- PAK5 | c.1190C>A p.T397K | Missense Mutation (SNP) | VAF 35/199 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0.145); catalogued as COSV62026383, COSV62026965; called by muse, mutect2, varscan2
- PCDH10 | c.2569G>T p.V857F | Missense Mutation (SNP) | VAF 46/247 reads (19%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.831); catalogued as COSV52093486; called by muse, mutect2, varscan2
- PCDH15 | c.3160A>G p.M1054V | Missense Mutation (SNP) | VAF 38/392 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767615507; called by muse, mutect2, varscan2
- PCDH17 | c.607C>A p.R203S | Missense Mutation (SNP) | VAF 25/278 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64974054; called by muse, mutect2
- PCDHA2 | c.2119G>T p.V707L | Missense Mutation (SNP) | VAF 160/482 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.927); catalogued as COSV65364292; called by muse, mutect2, varscan2
- PCK2 | c.877G>T p.G293W | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99394515; called by muse, mutect2
- PDE9A | c.130G>C p.G44R | Missense Mutation (SNP) | VAF 47/287 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); catalogued as rs756737949; called by muse, mutect2, varscan2
- PDPN | c.121G>T p.V41F (on ENST00000621990; = p.V117F on NM_006474.4) | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.2); catalogued as COSV99611230; called by muse, mutect2, varscan2
- PEG3 | c.595G>T p.V199L | Missense Mutation (SNP) | VAF 53/204 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1373584900; called by muse, mutect2, varscan2
- PEX1 | c.3053A>G p.N1018S | Missense Mutation (SNP) | VAF 85/339 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1337481084; called by muse, varscan2
- PFAS | c.326G>T p.R109L | Missense Mutation (SNP) | VAF 44/175 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1192661049, COSV58979769; called by muse, mutect2, varscan2
- PGR | c.2291G>A p.G764E | Missense Mutation (SNP) | VAF 62/278 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54796608; called by muse, varscan2
- PHC1 | c.447G>A p.M149I | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as rs369233170; called by muse, mutect2, varscan2
- PHF12 | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 29/187 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.516); catalogued as rs1260943967; called by muse, mutect2, varscan2
- PIK3R3 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 32/248 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.194); catalogued as COSV53109815; called by muse, mutect2, varscan2
- PIK3R5 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 33/99 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as COSV99353283; called by muse, mutect2, varscan2
- PIR | c.243C>G p.H81Q | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV62917126; called by muse, varscan2
- PKD1L2 | c.136G>T p.G46* | Nonsense Mutation (SNP) | VAF 123/442 reads (28%) | catalogued as COSV100449798; called by muse, mutect2, varscan2
- PKHD1L1 | c.3316G>T p.G1106C | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.868); catalogued as rs1243228650; called by mutect2, varscan2
- PKP2 | c.2578-1G>T p.X860_splice | Splice Site (SNP) | VAF 67/649 reads (10%) | catalogued as COSV99297114; called by muse, mutect2, varscan2
- PLA2G4D | c.1210C>A p.R404S | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV51819095; called by muse, mutect2, varscan2
- PLCB4 | c.568G>T p.G190C | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765694096; called by muse, mutect2, varscan2
- PLEKHA3 | c.716G>T p.R239L | Missense Mutation (SNP) | VAF 44/242 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as COSV99317729; called by muse, varscan2
- PLXNB2 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 91/223 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63784930; called by muse, mutect2, varscan2
- POLD1 | c.3090G>T p.Q1030H | Missense Mutation (SNP) | VAF 19/187 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs1403723642; called by muse, mutect2
- PPP2R1A | c.685G>A p.V229M | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as COSV59043133, COSV59043861; called by muse, mutect2, varscan2
- PPP3CA | c.1429G>T p.D477Y | Missense Mutation (SNP) | VAF 35/178 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100548076, COSV59921233; called by muse, mutect2, varscan2
- PRDM9 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 26/734 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV57005334; called by muse, mutect2
- PREX2 | c.1044del p.K349Sfs*9 | Frame Shift Del (DEL) | VAF 29/149 reads (19%) | catalogued as COSV55770371; called by mutect2, pindel, varscan2
- PRR15 | c.256C>A p.R86S | Missense Mutation (SNP) | VAF 75/333 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs1351425271, COSV60502297; called by muse, mutect2, varscan2
- PRSS1 | c.554G>T p.C185F | Missense Mutation (SNP) | VAF 59/402 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100298063; called by muse, mutect2, varscan2
- PRUNE2 | c.5334G>C p.Q1778H | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.071); catalogued as rs1474159363; called by muse, mutect2, varscan2
- PSAT1 | c.320G>T p.W107L | Missense Mutation (SNP) | VAF 37/351 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs753426182; called by muse, mutect2
- PSD4 | c.768C>G p.C256W | Missense Mutation (SNP) | VAF 47/204 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.103); catalogued as COSV55530624; called by muse, mutect2, varscan2
- PTPRB | c.500C>A p.P167Q | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.474); catalogued as COSV100546571; called by muse, mutect2, varscan2
- QSER1 | c.2968G>T p.D990Y (on ENST00000399302; = p.D1119Y on NM_001076786.3) | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as rs957851789; called by muse, mutect2
- RAPGEF6 | c.2407G>T p.E803* | Nonsense Mutation (SNP) | VAF 40/119 reads (34%) | catalogued as COSV57254306; called by muse, mutect2, varscan2
- RASIP1 | c.2168C>A p.P723H | Missense Mutation (SNP) | VAF 86/256 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV55803291; called by muse, mutect2, varscan2
- RCC1L | c.343G>A p.G115S | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs781796275; called by muse, mutect2
- RDH8 | c.353C>A p.P118H (on ENST00000651512; = p.P98H on NM_015725.4) | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50674934; called by muse, mutect2, varscan2
- REG1B | c.363C>A p.Y121* | Nonsense Mutation (SNP) | VAF 51/211 reads (24%) | catalogued as COSV59307373; called by muse, mutect2, varscan2
- REG3G | c.170C>A p.S57* | Nonsense Mutation (SNP) | VAF 32/130 reads (25%) | catalogued as COSV99709775; called by muse, mutect2, varscan2
- RFX4 | c.1220G>A p.R407H (on ENST00000392842 / NM_213594.3; = p.R313H on NM_032491.6) | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.976); catalogued as rs773180417, COSV57576748; called by muse, mutect2, varscan2
- RIF1 | c.1258G>T p.G420* | Nonsense Mutation (SNP) | VAF 40/194 reads (21%) | catalogued as COSV99690869; called by muse, mutect2, varscan2
- RIMBP2 | c.1397C>G p.P466R | Missense Mutation (SNP) | VAF 45/207 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55486032; called by muse, mutect2, varscan2
- RIMS2 | c.1491G>C p.K497N (on ENST00000666250 / NM_001348490.2; = p.K305N on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/370 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); catalogued as COSV51700314; called by muse, mutect2, varscan2
- RNF123 | c.397+1G>T p.X133_splice | Splice Site (SNP) | VAF 35/293 reads (12%) | catalogued as COSV59689797; called by muse, mutect2, varscan2
- RNF214 | c.376G>T p.E126* | Nonsense Mutation (SNP) | VAF 98/329 reads (30%) | catalogued as COSV56117706, COSV56121299; called by muse, mutect2, varscan2
- RRAS2 | c.67G>T p.G23C | Missense Mutation (SNP) | VAF 44/204 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56329700, COSV56329705; called by muse, mutect2, varscan2
- RREB1 | c.2515G>T p.A839S | Missense Mutation (SNP) | VAF 6/113 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV58561047; called by muse, mutect2
- RSPH14 | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 40/288 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99320918; called by muse, varscan2
- RXFP3 | c.526A>G p.M176V | Missense Mutation (SNP) | VAF 123/292 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57505658; called by muse, mutect2, varscan2
- RYR2 | c.4461G>T p.M1487I | Missense Mutation (SNP) | VAF 44/314 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as COSV63708249; called by mutect2, varscan2
- RYR2 | c.5275C>A p.P1759T | Missense Mutation (SNP) | VAF 93/322 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.37); catalogued as COSV63717162; called by muse, mutect2, varscan2
- SCN3A | c.4374C>A p.F1458L | Missense Mutation (SNP) | VAF 50/226 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as COSV51810931; called by muse, mutect2, varscan2
- SCN7A | c.4122G>T p.M1374I | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs1218375087; called by muse, mutect2, varscan2
- SCN9A | c.435G>T p.M145I | Missense Mutation (SNP) | VAF 72/451 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV100313448; called by muse, mutect2, varscan2
- SDS | c.203C>A p.A68E | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57453674; called by muse, mutect2
- SERPINA3 | c.578C>A p.T193K | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1230719721; called by muse, mutect2, varscan2
- SHOX2 | c.340A>T p.T114S | Missense Mutation (SNP) | VAF 42/308 reads (14%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.001); catalogued as COSV55827249; called by muse, mutect2, varscan2
- SI | c.5027C>G p.A1676G | Missense Mutation (SNP) | VAF 76/373 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV52281375; called by muse, mutect2, varscan2
- SI | c.1501G>A p.G501R | Missense Mutation (SNP) | VAF 53/322 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100016156, COSV52264417; called by muse, mutect2, varscan2
- SI | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 45/188 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.526); catalogued as rs750638301; called by muse, varscan2
- SIRPB2 | c.817G>T p.A273S | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV63124800; called by muse, mutect2, varscan2
- SLC12A9 | c.643G>T p.G215W | Missense Mutation (SNP) | VAF 35/308 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as rs775068338, COSV51935558; called by muse, mutect2, varscan2
- SLC17A6 | c.1096G>T p.G366W | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1408660137; called by muse, varscan2
- SLC35A4 | c.370G>A p.G124R | Missense Mutation (SNP) | VAF 19/326 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV100021193; called by muse, mutect2
- SLC40A1 | c.1666G>T p.D556Y | Missense Mutation (SNP) | VAF 54/313 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.259); catalogued as COSV99656382; called by muse, mutect2, varscan2
- SLC9C1 | c.241C>A p.R81S | Missense Mutation (SNP) | VAF 71/264 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.018); catalogued as rs749177716, COSV59886093; called by muse, mutect2, varscan2
- SLITRK6 | c.1529C>T p.T510I | Missense Mutation (SNP) | VAF 52/225 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV68391392; called by muse, mutect2, varscan2
- SMOC1 | c.1207C>A p.R403S | Missense Mutation (SNP) | VAF 77/330 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as rs1322307106, COSV62763402; called by muse, mutect2, varscan2
- SOAT2 | c.315C>G p.I105M | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.079); catalogued as COSV56856928; called by muse, mutect2, varscan2
- SOHLH2 | c.579G>T p.L193F | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.546); catalogued as COSV58522765; called by muse, mutect2, varscan2
- SORCS1 | c.3070G>T p.V1024L | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as COSV99544313; called by muse, mutect2, varscan2
- SOS1 | c.1309A>T p.I437F | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV67677990; called by muse, mutect2, varscan2
- SOX9 | c.549G>T p.K183N | Missense Mutation (SNP) | VAF 124/481 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV55428407; called by muse, mutect2, varscan2
- SPEF2 | c.2893G>T p.E965* | Nonsense Mutation (SNP) | VAF 68/374 reads (18%) | catalogued as COSV61544106; called by muse, varscan2
- SPEG | c.4885G>T p.A1629S | Missense Mutation (SNP) | VAF 94/359 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56665486; called by muse, mutect2, varscan2
- SPOCD1 | c.1307G>T p.R436L | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV57100968; called by muse, mutect2
- SPTA1 | c.6174G>A p.W2058* | Nonsense Mutation (SNP) | VAF 31/198 reads (16%) | catalogued as COSV63749508; called by muse, mutect2, varscan2
- STRC | c.3512G>T p.W1171L | Missense Mutation (SNP) | VAF 81/380 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as COSV68660714; called by muse, mutect2, varscan2
- STXBP5L | c.1285C>A p.L429M | Missense Mutation (SNP) | VAF 34/218 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99877264; called by muse, mutect2, varscan2
- STYXL2 | c.3175C>A p.R1059S | Missense Mutation (SNP) | VAF 46/287 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs147410196; called by muse, mutect2, varscan2
- SYT12 | c.1225C>G p.R409G | Missense Mutation (SNP) | VAF 52/205 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67353402; called by muse, mutect2, varscan2
- TACR3 | c.52G>T p.G18C | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.237); catalogued as COSV59209059, COSV99079947; called by muse, mutect2, varscan2
- TBX4 | c.1055G>T p.R352L | Missense Mutation (SNP) | VAF 69/326 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs61739275, COSV99540080; called by muse, mutect2, varscan2
- TECTA | c.1715C>T p.A572V | Missense Mutation (SNP) | VAF 80/451 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as rs772636065; called by muse, mutect2, varscan2
- TET2 | c.3619G>A p.E1207K | Missense Mutation (SNP) | VAF 57/199 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54395743, COSV54420483; called by muse, mutect2, varscan2
- TEX26 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 36/209 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs149667533; called by muse, mutect2, varscan2
- TH | c.1188G>T p.K396N (on ENST00000381178 / NM_199292.3; = p.K365N on NM_000360.4) | Missense Mutation (SNP) | VAF 45/239 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs865862783; called by muse, mutect2, varscan2
- THSD7B | c.4369G>T p.V1457F (on ENST00000272643; = p.V1455F on NM_001316349.2) | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV99752663; called by muse, mutect2, varscan2
- TKTL2 | c.1824G>T p.M608I | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV54919236; called by muse, mutect2
- TLR4 | c.2144G>T p.G715V (on ENST00000355622 / NM_138554.5; = p.G675V on NM_003266.4) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1157906794, COSV62924006; called by muse, mutect2, varscan2
- TM9SF2 | c.1465G>T p.A489S | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated (0.64); PolyPhen benign (0.086); catalogued as rs747882772; called by muse, mutect2, varscan2
- TMBIM4 | c.67G>C p.V23L | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as rs1021975268; called by muse, mutect2, varscan2
- TMEM255B | c.733C>A p.Q245K | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.364); catalogued as COSV64713884; called by muse, mutect2
- TMEM260 | c.1750G>T p.V584L | Missense Mutation (SNP) | VAF 48/246 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs150375138; called by muse, mutect2, varscan2
- TMPRSS11E | c.1022C>A p.T341N | Missense Mutation (SNP) | VAF 45/223 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.289); catalogued as rs149009844; called by muse, varscan2
- TMPRSS5 | c.208C>T p.L70= | Splice Region (SNP) | VAF 18/83 reads (22%) | catalogued as rs907936744; called by muse, varscan2
- TNN | c.605G>T p.C202F | Missense Mutation (SNP) | VAF 59/220 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764615697; called by muse, mutect2, varscan2
- TOP1MT | c.895G>T p.A299S | Missense Mutation (SNP) | VAF 24/219 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.038); catalogued as rs756349997; called by muse, mutect2, varscan2
- TPP2 | c.841G>T p.E281* | Nonsense Mutation (SNP) | VAF 5/77 reads (6%) | catalogued as COSV65752989; called by muse, mutect2
- TRIM51 | c.1141G>A p.G381R | Missense Mutation (SNP) | VAF 131/646 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as rs776737248, COSV99792176; called by muse, mutect2, varscan2
- TRIM67 | c.860C>A p.A287E | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.22); catalogued as rs376673550, COSV64158189; called by muse, varscan2
- TRPC6 | c.1665G>T p.Q555H | Missense Mutation (SNP) | VAF 69/262 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100723778, COSV60258921; called by muse, mutect2, varscan2
- TRPM6 | c.5950G>T p.D1984Y | Missense Mutation (SNP) | VAF 31/244 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV62514899; called by muse, mutect2, varscan2
- TSPAN32 | c.137G>T p.R46L | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs371441475; called by muse, mutect2
- TTC22 | c.415G>T p.A139S | Missense Mutation (SNP) | VAF 22/218 reads (10%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs1219075398; called by muse, mutect2
- TTLL6 | c.235G>C p.A79P | Missense Mutation (SNP) | VAF 110/674 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as COSV64979944; called by muse, varscan2
- TTN | c.33994G>C p.E11332Q (on ENST00000591111; = p.E10405Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/403 reads (19%) | PolyPhen benign (0.368); catalogued as COSV60432785; called by muse, mutect2, varscan2
- TTN | c.18845del p.G6282Efs*7 (on ENST00000591111; = p.G5355Efs*7 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 25/137 reads (18%) | catalogued as COSV60299928; called by mutect2, pindel, varscan2
- TTN | c.8834C>A p.T2945K (on ENST00000591111; = p.T2899K on NM_003319.4) | Missense Mutation (SNP) | VAF 71/356 reads (20%) | PolyPhen benign (0); catalogued as COSV60280503; called by muse, mutect2, varscan2
- UGT2A2 | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.419); catalogued as COSV54147643, COSV99683923; called by muse, mutect2, varscan2
- UNC13C | c.4306G>T p.G1436C | Missense Mutation (SNP) | VAF 103/349 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV99516941; called by muse, mutect2, varscan2
- UNC45B | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 77/344 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs768039568, COSV99268541; called by muse, mutect2, varscan2
- UQCRFS1 | c.152G>T p.S51I | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.079); catalogued as rs1217282553; called by muse, mutect2, varscan2
- URM1 | c.19G>T p.V7L | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as COSV65717018; called by muse, mutect2
- USH2A | c.9801C>A p.C3267* | Nonsense Mutation (SNP) | VAF 105/426 reads (25%) | catalogued as CM153044; called by muse, mutect2, varscan2
- USP7 | c.1657C>T p.Q553* | Nonsense Mutation (SNP) | VAF 9/159 reads (6%) | catalogued as COSV61214288; called by muse, mutect2
- VCX3B | c.26G>T p.G9V | Missense Mutation (SNP) | VAF 92/550 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); catalogued as COSV66842520; called by muse, mutect2, varscan2
- VRK1 | c.1069-1G>C p.X357_splice | Splice Site (SNP) | VAF 57/333 reads (17%) | catalogued as COSV53711133; called by muse, mutect2, varscan2
- WDR49 | c.1649A>T p.E550V (on ENST00000308378 / NM_001366158.1; = p.E891V on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/188 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.725); catalogued as COSV100392732, COSV57711209; called by muse, mutect2, varscan2
- XIRP2 | c.1594C>A p.L532I (on ENST00000628543; = p.L707I on NM_152381.6) | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as COSV99748367; called by muse, mutect2, varscan2
- XIRP2 | c.6877G>T p.V2293L (on ENST00000628543; = p.V2468L on NM_152381.6) | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs540282598, COSV54714168; called by muse, mutect2, varscan2
- ZBTB21 | c.1933G>A p.G645S | Missense Mutation (SNP) | VAF 54/240 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.163); catalogued as COSV60405482; called by muse, mutect2, varscan2
- ZC3H3 | c.2573C>T p.P858L | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1413981145; called by muse, varscan2
- ZFHX4 | c.5263G>T p.G1755C | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); catalogued as rs757372232; called by muse, mutect2, varscan2
- ZFR2 | c.509C>T p.T170M | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs201894571; called by muse, mutect2, varscan2
- ZNF292 | c.517G>T p.E173* | Nonsense Mutation (SNP) | VAF 70/234 reads (30%) | catalogued as COSV60538677; called by muse, varscan2
- ZNF479 | c.1475C>A p.P492H | Missense Mutation (SNP) | VAF 83/323 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV58642846; called by muse, mutect2, varscan2
- ZNF536 | c.490G>T p.D164Y | Missense Mutation (SNP) | VAF 24/261 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV62817522; called by muse, mutect2
- ZNF552 | c.868C>A p.H290N | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66971894; called by muse, mutect2, varscan2
- ZNF560 | c.1054G>T p.E352* | Nonsense Mutation (SNP) | VAF 55/162 reads (34%) | catalogued as rs1376388250, COSV56868878; called by muse, mutect2, varscan2
- ZNF568 | c.1328G>T p.R443I | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV71279152; called by muse, mutect2
- ZNF607 | c.986G>C p.R329T | Missense Mutation (SNP) | VAF 21/255 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as COSV67696321; called by muse, mutect2
- ZNF615 | c.6G>T p.M2I | Missense Mutation (SNP) | VAF 49/213 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748956253; called by muse, mutect2, varscan2
- ZNF676 | c.140C>A p.A47D (on ENST00000650058; = p.A15D on NM_001001411.3) | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.204); catalogued as rs750900675; called by muse, mutect2, varscan2
- ZNF835 | c.163G>T p.D55Y | Missense Mutation (SNP) | VAF 150/504 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.612); catalogued as COSV73379353; called by muse, mutect2, varscan2
- ZNF865 | c.1339G>T p.G447C | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); catalogued as COSV101642807; called by muse, mutect2, varscan2
- ZNF883 | c.767A>G p.Q256R | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.198); catalogued as rs1330217031; called by muse, mutect2, varscan2
- ABCA12 | c.4028C>T p.T1343I (on ENST00000272895 / NM_173076.3; = p.T1025I on NM_015657.3) | Missense Mutation (SNP) | VAF 49/406 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- ABCA13 | c.2327A>T p.N776I | Missense Mutation (SNP) | VAF 101/397 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- ABCA13 | c.2423G>T p.G808V | Missense Mutation (SNP) | VAF 58/407 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ABCA4 | c.6360del p.R2121Gfs*24 | Frame Shift Del (DEL) | VAF 52/358 reads (15%) | called by mutect2, pindel, varscan2
- ABCC9 | c.1954C>A p.L652M | Missense Mutation (SNP) | VAF 35/232 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ABCF1 | c.1789G>T p.E597* (on ENST00000326195 / NM_001025091.2; = p.E559* on NM_001090.3) | Nonsense Mutation (SNP) | VAF 58/143 reads (41%) | called by muse, mutect2, varscan2
- ABL2 | c.2686G>T p.G896W (on ENST00000502732 / NM_007314.4; = p.G881W on NM_005158.5) | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- ACACB | c.3388G>T p.V1130L | Missense Mutation (SNP) | VAF 22/259 reads (8%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); called by muse, mutect2
- ACE | c.2107del p.Q703Rfs*7 | Frame Shift Del (DEL) | VAF 60/792 reads (8%) | called by mutect2, pindel
- ACKR1 | c.310G>T p.V104L | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ACKR2 | c.184A>T p.S62C | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2
- ACOD1 | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 75/361 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ACSM4 | c.1390T>A p.Y464N | Missense Mutation (SNP) | VAF 26/264 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- ACTN2 | c.1800C>A p.S600R | Missense Mutation (SNP) | VAF 110/476 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADAM20 | c.246G>T p.L82F | Missense Mutation (SNP) | VAF 14/282 reads (5%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.788); called by muse, mutect2
- ADAMTS12 | c.4147G>T p.G1383C | Missense Mutation (SNP) | VAF 35/207 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADAMTS15 | c.2544G>T p.W848C | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS19 | c.2636G>T p.G879V | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS5 | c.2569C>A p.P857T | Missense Mutation (SNP) | VAF 37/231 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ADAMTS5 | c.767G>T p.W256L | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS6 | c.2639A>T p.Y880F | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ADAMTS8 | c.1213T>A p.W405R | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADARB2 | c.617C>A p.P206Q | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.021); called by muse, varscan2
- ADARB2 | c.542_543insA p.A182Gfs*207 | Frame Shift Ins (INS) | VAF 5/47 reads (11%) | called by pindel, varscan2
- ADCY2 | c.893G>T p.G298V | Missense Mutation (SNP) | VAF 65/278 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- ADGRA2 | c.106G>T p.G36C | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ADGRB1 | c.1188G>T p.E396D | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ADGRD2 | c.2300del p.V768Wfs*11 | Frame Shift Del (DEL) | VAF 35/295 reads (12%) | called by mutect2, pindel, varscan2
- ADIPOR1 | c.1114G>C p.D372H | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- ADM | c.108G>T p.K36N | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.962); called by muse, mutect2
- AGFG2 | c.890G>T p.G297V | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- AGL | c.4048G>T p.E1350* | Nonsense Mutation (SNP) | VAF 34/292 reads (12%) | called by muse, varscan2
- AHNAK2 | c.13045C>A p.Q4349K | Missense Mutation (SNP) | VAF 45/494 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.937); called by muse, mutect2
- AIPL1 | c.422A>T p.Q141L | Missense Mutation (SNP) | VAF 95/385 reads (25%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- AIRE | c.1426T>A p.S476T | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.081); called by muse, mutect2
- AK4 | c.185T>A p.L62H | Missense Mutation (SNP) | VAF 31/182 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- AKR1C2 | c.680+2T>A p.X227_splice | Splice Site (SNP) | VAF 20/204 reads (10%) | called by muse, mutect2
- AMER3 | c.1122C>A p.S374R | Missense Mutation (SNP) | VAF 59/314 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by mutect2, varscan2
- ANHX | c.533C>A p.P178H | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- ANK3 | c.9482G>T p.S3161I | Missense Mutation (SNP) | VAF 21/261 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.462); called by muse, mutect2
- ANKRD18A | c.1148C>A p.T383K | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- ANKRD20A1 | c.1532T>G p.M511R | Missense Mutation (SNP) | VAF 18/203 reads (9%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD31 | c.3292del p.R1098Gfs*6 | Frame Shift Del (DEL) | VAF 22/96 reads (23%) | called by pindel, varscan2
- ANKRD34A | c.266G>T p.G89V | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.303); called by muse, mutect2
- ANKRD34C | c.320A>T p.E107V | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ANKS1B | c.3290A>T p.E1097V (on ENST00000547776 / NM_152788.4; = p.E263V on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANO1 | c.955C>A p.L319M | Missense Mutation (SNP) | VAF 34/231 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANO4 | c.263A>T p.Q88L | Missense Mutation (SNP) | VAF 96/460 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- ANO4 | c.265G>T p.A89S | Missense Mutation (SNP) | VAF 94/444 reads (21%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); called by muse, mutect2
- ANO4 | c.503C>G p.P168R (on ENST00000392977 / NM_001286615.2; = p.P133R on NM_178826.4) | Missense Mutation (SNP) | VAF 19/234 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- ANPEP | c.2327del p.F776Sfs*66 | Frame Shift Del (DEL) | VAF 43/153 reads (28%) | called by mutect2, pindel, varscan2
- AOX1 | c.1616C>A p.P539Q | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2
- AOX1 | c.3856G>C p.A1286P | Missense Mutation (SNP) | VAF 59/228 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AP2A2 | c.2398C>G p.P800A | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- AP3D1 | c.355G>T p.D119Y | Missense Mutation (SNP) | VAF 50/214 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- APBB1IP | c.49G>T p.G17* | Nonsense Mutation (SNP) | VAF 14/116 reads (12%) | called by muse, mutect2, varscan2
- APCDD1 | c.1353G>T p.R451S | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.053); called by mutect2, varscan2
- APLNR | c.1056G>T p.Q352H | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- APOBEC3A | c.583C>A p.Q195K | Missense Mutation (SNP) | VAF 45/260 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ARHGAP12 | c.108A>T p.Q36H | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- ARHGAP20 | c.1537G>T p.V513F | Missense Mutation (SNP) | VAF 71/280 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.404); called by muse, varscan2
- ARHGAP32 | c.685A>G p.K229E | Missense Mutation (SNP) | VAF 60/300 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- ARHGAP42 | c.2554C>A p.P852T | Missense Mutation (SNP) | VAF 64/205 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGEF11 | c.1828G>T p.G610C | Missense Mutation (SNP) | VAF 28/214 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2
- ARHGEF11 | c.1826T>G p.L609R | Missense Mutation (SNP) | VAF 30/206 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARHGEF18 | c.755G>T p.C252F (on ENST00000359920 / NM_001130955.2; = p.C148F on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 139/382 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- ARHGEF26 | c.1771-1G>T p.X591_splice | Splice Site (SNP) | VAF 30/156 reads (19%) | called by muse, mutect2, varscan2
- ARMCX5 | c.955C>T p.L319F | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ARPP21 | c.1361G>T p.G454V | Missense Mutation (SNP) | VAF 72/328 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- ARSH | c.1638C>A p.F546L | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- ASB18 | c.258C>A p.N86K | Missense Mutation (SNP) | VAF 165/429 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- ASIC4 | c.179C>A p.P60Q | Missense Mutation (SNP) | VAF 101/255 reads (40%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- ASPDH | c.436C>A p.L146I (on ENST00000389208 / NM_001114598.2; = p.L41I on NM_001024656.3) | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ASPM | c.2961G>C p.Q987H | Missense Mutation (SNP) | VAF 124/490 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.894); called by muse, varscan2
- ASTN2 | c.1120C>A p.L374M | Missense Mutation (SNP) | VAF 35/256 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ATM | c.798G>T p.W266C | Missense Mutation (SNP) | VAF 56/333 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP2B4 | c.234G>T p.Q78H | Missense Mutation (SNP) | VAF 89/360 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.04); called by muse, varscan2
- ATP6V0D2 | c.1022C>G p.T341S | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- ATP6V1E2 | c.247G>T p.V83F | Missense Mutation (SNP) | VAF 44/169 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- ATRNL1 | c.2267G>T p.G756V | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- ATRNL1 | c.2328C>A p.C776* | Nonsense Mutation (SNP) | VAF 31/183 reads (17%) | called by muse, varscan2
- ATXN7 | c.391del p.E131Kfs*92 | Frame Shift Del (DEL) | VAF 32/181 reads (18%) | called by mutect2, pindel, varscan2
- AVPR1A | c.109G>T p.E37* | Nonsense Mutation (SNP) | VAF 30/200 reads (15%) | called by muse, mutect2, varscan2
- BABAM2 | c.287C>A p.P96H | Missense Mutation (SNP) | VAF 51/268 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- BAD | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.629); called by muse, mutect2
- BAG6 | c.2653del p.E885Sfs*36 (on ENST00000676571; = p.E838Sfs*36 on NM_080702.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 68/200 reads (34%) | called by mutect2, pindel*, varscan2
- BATF2 | c.784C>A p.L262M | Missense Mutation (SNP) | VAF 54/236 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- BEND4 | c.280G>T p.A94S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- BEST4 | c.539A>T p.K180M | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.823); called by muse, mutect2
- BHLHE23 | c.598C>A p.L200M (on ENST00000370346; = p.L216M on NM_080606.4) | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- BIRC7 | c.20C>A p.A7D | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, varscan2
- BMPER | c.1353_1354del p.P452Tfs*52 | Frame Shift Del (DEL) | VAF 81/272 reads (30%) | called by pindel, varscan2
- BOD1L1 | c.5134G>T p.G1712* | Nonsense Mutation (SNP) | VAF 34/236 reads (14%) | called by muse, mutect2, varscan2
- BOD1L2 | c.247C>A p.H83N | Missense Mutation (SNP) | VAF 76/254 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- BPIFB2 | c.987C>G p.H329Q | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- BPIFB6 | c.97+2T>A p.X33_splice | Splice Site (SNP) | VAF 39/198 reads (20%) | called by muse, mutect2, varscan2
- BRINP2 | c.1892dup p.L631Ffs*4 | Frame Shift Ins (INS) | VAF 24/195 reads (12%) | called by mutect2, pindel, varscan2
- BRMS1 | c.107G>T p.G36V | Missense Mutation (SNP) | VAF 62/267 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- BRPF1 | c.530C>G p.P177R | Missense Mutation (SNP) | VAF 25/272 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- BSND | c.86A>G p.D29G | Missense Mutation (SNP) | VAF 24/194 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, varscan2
- BST1 | c.868C>G p.Q290E | Missense Mutation (SNP) | VAF 11/145 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2
- BTLA | c.100T>C p.C34R | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- C10orf90 | c.803A>T p.D268V | Missense Mutation (SNP) | VAF 65/262 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- C17orf64 | c.266G>T p.G89V | Missense Mutation (SNP) | VAF 70/277 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C1QL2 | c.332C>A p.S111* | Nonsense Mutation (SNP) | VAF 30/182 reads (16%) | called by muse, mutect2, varscan2
- C1orf158 | c.562C>A p.L188M | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- C1orf35 | c.517G>T p.D173Y | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- C1orf87 | c.278A>T p.Q93L | Missense Mutation (SNP) | VAF 36/340 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, varscan2
- C20orf194 | c.1189-1G>T p.X397_splice | Splice Site (SNP) | VAF 37/223 reads (17%) | called by muse, mutect2, varscan2
- C3orf38 | c.518G>T p.W173L | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.374); called by muse, mutect2
- C4orf54 | c.3428G>C p.G1143A | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- C5orf49 | c.411G>T p.K137N | Missense Mutation (SNP) | VAF 73/318 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.095); called by mutect2, varscan2
- C8B | c.638C>A p.P213H | Missense Mutation (SNP) | VAF 64/465 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CA10 | c.918G>T p.Q306H | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- CACNA1A | c.2962C>T p.R988W | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- CACNA1B | c.2951A>G p.K984R | Missense Mutation (SNP) | VAF 32/316 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CACNA1C | c.2884G>T p.G962C | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- CACNA1I | c.2209C>G p.R737G | Missense Mutation (SNP) | VAF 62/368 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CACNA1S | c.5096C>T p.T1699I | Missense Mutation (SNP) | VAF 179/636 reads (28%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CACNA2D1 | c.1906G>C p.E636Q (on ENST00000356253 / NM_001366867.1; = p.E617Q on NM_000722.4) | Missense Mutation (SNP) | VAF 64/369 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.381); called by muse, varscan2
- CACUL1 | c.1026G>T p.R342S | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- CADM2 | c.698C>A p.P233Q (on ENST00000407528 / NM_001167674.2; = p.P235Q on NM_153184.4) | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CADM3 | c.761G>A p.C254Y (on ENST00000368125 / NM_001127173.3; = p.C288Y on NM_021189.5) | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CAMK4 | c.1104C>G p.D368E | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAPN8 | c.1075G>A p.V359I | Missense Mutation (SNP) | VAF 50/429 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CASP2 | c.1025G>T p.G342V | Missense Mutation (SNP) | VAF 70/388 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- CBLN2 | c.475C>G p.Q159E | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- CBWD6 | c.1081+5G>C | Splice Region (SNP) | VAF 23/381 reads (6%) | called by muse, mutect2
- CCDC116 | c.956A>T p.Q319L | Missense Mutation (SNP) | VAF 36/225 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- CCDC124 | c.415G>C p.E139Q | Missense Mutation (SNP) | VAF 56/429 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- CCDC136 | c.2335A>T p.T779S | Missense Mutation (SNP) | VAF 54/512 reads (11%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.003); called by muse, mutect2
- CCDC15 | c.2744G>T p.R915L | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, varscan2
- CCDC168 | c.19809del p.L6603Ffs*12 | Frame Shift Del (DEL) | VAF 20/142 reads (14%) | called by mutect2, varscan2
- CCDC168 | c.19808del p.L6603Cfs*12 | Frame Shift Del (DEL) | VAF 22/153 reads (14%) | called by mutect2*, pindel, varscan2*
- CCDC168 | c.8194C>A p.L2732I | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- CCDC168 | c.6591G>C p.W2197C | Missense Mutation (SNP) | VAF 48/224 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CCDC188 | c.844C>A p.L282I | Missense Mutation (SNP) | VAF 51/293 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CCDC39 | c.1108del p.V370* | Frame Shift Del (DEL) | VAF 48/230 reads (21%) | called by mutect2, pindel, varscan2
- CCL23 | c.405G>C p.R135S | Missense Mutation (SNP) | VAF 68/195 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CCL4L2 | c.76A>T p.M26L | Missense Mutation (SNP) | VAF 106/474 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CD163 | c.1228G>T p.V410F | Missense Mutation (SNP) | VAF 74/504 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- CD163L1 | c.1139G>T p.G380V | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD19 | c.1219G>T p.E407* | Nonsense Mutation (SNP) | VAF 65/255 reads (25%) | called by muse, mutect2, varscan2
- CD1C | c.780del p.T261Hfs*6 | Frame Shift Del (DEL) | VAF 54/424 reads (13%) | called by mutect2, pindel, varscan2
- CD7 | c.661G>T p.V221L | Missense Mutation (SNP) | VAF 46/321 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- CDAN1 | c.1207C>T p.P403S | Missense Mutation (SNP) | VAF 138/471 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.509); called by muse, mutect2, varscan2
- CDH12 | c.1643C>A p.A548E | Missense Mutation (SNP) | VAF 78/272 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDH12 | c.1591G>T p.E531* | Nonsense Mutation (SNP) | VAF 33/497 reads (7%) | called by muse, mutect2
- CDH19 | c.1999dup p.E667Gfs*11 | Frame Shift Ins (INS) | VAF 31/135 reads (23%) | called by mutect2, pindel, varscan2
- CDH22 | c.462C>A p.F154L | Missense Mutation (SNP) | VAF 49/259 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDH23 | c.1957A>T p.S653C | Missense Mutation (SNP) | VAF 31/240 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CDH5 | c.2260G>T p.D754Y | Missense Mutation (SNP) | VAF 58/290 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CDH9 | c.1772G>T p.C591F | Missense Mutation (SNP) | VAF 257/902 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH9 | c.380G>T p.R127L | Missense Mutation (SNP) | VAF 95/805 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- CDK11A | c.1078G>A p.V360I (on ENST00000378633 / NM_001313896.2; = p.V357I on NM_024011.4) | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- CDKL4 | c.981G>T p.Q327H | Missense Mutation (SNP) | VAF 61/254 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDKL5 | c.1282G>T p.G428C | Missense Mutation (SNP) | VAF 126/324 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- CDON | c.1476G>C p.Q492H | Missense Mutation (SNP) | VAF 31/185 reads (17%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.485); called by muse, mutect2, varscan2
- CDX2 | c.561C>A p.D187E | Missense Mutation (SNP) | VAF 15/160 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.383); called by muse, mutect2
- CEACAM20 | c.1181G>A p.G394E | Missense Mutation (SNP) | VAF 49/632 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- CELSR2 | c.5453G>T p.S1818I | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CENPL | c.590G>C p.G197A | Missense Mutation (SNP) | VAF 13/223 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.396); called by muse, mutect2
- CEP126 | c.1730G>T p.S577I | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CEP170 | c.1315G>T p.G439W | Missense Mutation (SNP) | VAF 105/417 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- CEP43 | c.810G>T p.R270S | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- CFAP69 | c.354_355del p.C118Wfs*12 | Frame Shift Del (DEL) | VAF 30/164 reads (18%) | called by pindel, varscan2
- CFHR1 | c.412C>G p.P138A | Missense Mutation (SNP) | VAF 55/235 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CGB5 | c.283G>T p.G95C | Missense Mutation (SNP) | VAF 23/706 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CGNL1 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 10/44 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.813); called by muse, varscan2
- CHRNA10 | c.1201A>T p.T401S | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHRNA7 | c.173G>T p.S58I | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- CIT | c.5894A>T p.E1965V | Missense Mutation (SNP) | VAF 38/186 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- CLCC1 | c.417G>C p.K139N | Missense Mutation (SNP) | VAF 37/238 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- CLDN3 | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CLVS1 | c.350G>T p.G117V | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- CNTLN | c.3294G>T p.Q1098H | Missense Mutation (SNP) | VAF 59/132 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.031); called by muse, varscan2
- CNTN1 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 27/225 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNTN5 | c.731G>T p.R244L | Missense Mutation (SNP) | VAF 67/355 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNTNAP2 | c.16C>A p.R6S | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- COL10A1 | c.1322C>A p.P441Q | Missense Mutation (SNP) | VAF 69/204 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- COL11A2 | c.4637C>A p.S1546* (on ENST00000341947 / NM_080680.3; = p.S1439* on NM_080679.2) | Nonsense Mutation (SNP) | VAF 40/579 reads (7%) | called by muse, mutect2
- COL14A1 | c.4579G>T p.G1527* | Nonsense Mutation (SNP) | VAF 22/177 reads (12%) | called by muse, mutect2, varscan2
- COL4A3 | c.650A>T p.H217L | Missense Mutation (SNP) | VAF 152/349 reads (44%) | SIFT tolerated (0.72); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- COL4A6 | c.517G>C p.D173H | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- COL5A3 | c.2389G>T p.G797* | Nonsense Mutation (SNP) | VAF 39/129 reads (30%) | called by muse, mutect2, varscan2
- COL6A5 | c.1654G>A p.D552N | Missense Mutation (SNP) | VAF 122/440 reads (28%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- COL6A5 | c.4609-1G>T p.X1537_splice | Splice Site (SNP) | VAF 34/119 reads (29%) | called by muse, mutect2, varscan2
- COL6A5 | c.5137G>T p.G1713* | Nonsense Mutation (SNP) | VAF 71/241 reads (29%) | called by muse, mutect2, varscan2
- COL7A1 | c.4722+2T>C p.X1574_splice | Splice Site (SNP) | VAF 138/650 reads (21%) | called by muse, mutect2, varscan2
- COL9A1 | c.2212C>A p.Q738K | Missense Mutation (SNP) | VAF 154/452 reads (34%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CPA4 | c.150G>T p.K50N | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.239); called by muse, varscan2
- CPA4 | c.1085C>A p.A362D | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- CPED1 | c.2816T>G p.M939R | Missense Mutation (SNP) | VAF 49/239 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CPT1A | c.1868C>G p.A623G | Missense Mutation (SNP) | VAF 113/427 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CPXM1 | c.833-1G>T p.X278_splice | Splice Site (SNP) | VAF 33/157 reads (21%) | called by muse, mutect2, varscan2
- CPXM2 | c.2150C>A p.T717K | Missense Mutation (SNP) | VAF 72/329 reads (22%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- CPXM2 | c.1667C>G p.A556G | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- CRB1 | c.2940C>G p.F980L | Missense Mutation (SNP) | VAF 59/240 reads (25%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CRH | c.98G>T p.G33V | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- CRISPLD1 | c.763G>T p.E255* | Nonsense Mutation (SNP) | VAF 18/141 reads (13%) | called by muse, mutect2, varscan2
- CRYBG1 | c.4804A>T p.T1602S | Missense Mutation (SNP) | VAF 82/233 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- CSMD1 | c.8137del p.V2714Wfs*5 (on ENST00000520002; = p.V2713Wfs*5 on NM_033225.6) | Frame Shift Del (DEL) | VAF 26/206 reads (13%) | called by pindel, varscan2
- CSMD1 | c.6734G>A p.G2245D (on ENST00000520002; = p.G2244D on NM_033225.6) | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSMD2 | c.4540_4541delinsT p.F1515Sfs*27 | Frame Shift Del (DEL) | VAF 39/246 reads (16%) | called by pindel, varscan2*
- CSMD2 | c.2319G>T p.K773N | Missense Mutation (SNP) | VAF 30/191 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSMD3 | c.1834G>T p.G612* (on ENST00000297405 / NM_001363185.1; = p.G508* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 60/441 reads (14%) | called by muse, mutect2, varscan2
- CSMD3 | c.554C>A p.P185H | Missense Mutation (SNP) | VAF 24/224 reads (11%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- CT47B1 | c.29C>G p.T10S | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- CT55 | c.332C>G p.T111S | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CTIF | c.301G>C p.A101P | Missense Mutation (SNP) | VAF 73/241 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- CTNNA2 | c.1351del p.A451Qfs*17 | Frame Shift Del (DEL) | VAF 24/195 reads (12%) | called by mutect2, pindel, varscan2
- CTR9 | c.2155G>T p.V719F | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- CYLC1 | c.200A>T p.E67V | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, varscan2
- CYP11B1 | c.1333T>A p.F445I | Missense Mutation (SNP) | VAF 62/385 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CYP11B2 | c.569C>A p.P190H | Missense Mutation (SNP) | VAF 111/502 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CYP46A1 | c.1196G>T p.G399V | Missense Mutation (SNP) | VAF 32/202 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CYP4F2 | c.1165C>A p.L389M | Missense Mutation (SNP) | VAF 84/343 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DACH1 | c.913A>T p.M305L | Missense Mutation (SNP) | VAF 19/208 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2
- DBX2 | c.784G>C p.E262Q | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- DCAF12L1 | c.1340G>T p.G447V | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DCAF12L1 | c.563G>T p.G188V | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCDC1 | c.4018C>A p.P1340T (on ENST00000597505 / NM_001367979.1; = p.P447T on NM_020869.3) | Missense Mutation (SNP) | VAF 52/251 reads (21%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- DCHS1 | c.9112G>C p.A3038P | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- DCN | c.749dup p.L250Ffs*12 | Frame Shift Ins (INS) | VAF 57/385 reads (15%) | called by mutect2, pindel, varscan2
- DEFB106A | c.112G>C p.G38R | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0); called by mutect2, varscan2
- DENND5B | c.2711G>T p.R904L | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- DHX16 | c.2467A>T p.M823L | Missense Mutation (SNP) | VAF 97/273 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- DIAPH1 | c.1064A>G p.N355S | Missense Mutation (SNP) | VAF 27/406 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); called by muse, mutect2
- DIO1 | c.541C>A p.L181M | Missense Mutation (SNP) | VAF 36/317 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- DISP3 | c.2578G>A p.V860M | Missense Mutation (SNP) | VAF 43/173 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DMC1 | c.587-1G>T p.X196_splice | Splice Site (SNP) | VAF 62/435 reads (14%) | called by muse, mutect2, varscan2
- DMD | c.9929A>T p.Q3310L | Missense Mutation (SNP) | VAF 55/146 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DMRT3 | c.611G>T p.G204V | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- DNAH11 | c.13190A>C p.N4397T | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- DNAH5 | c.11473A>G p.I3825V | Missense Mutation (SNP) | VAF 139/1072 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- DNAH7 | c.3982G>T p.G1328C | Missense Mutation (SNP) | VAF 53/202 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH7 | c.904A>T p.N302Y | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- DNAJC13 | c.1180-1G>T p.X394_splice | Splice Site (SNP) | VAF 34/136 reads (25%) | called by muse, mutect2, varscan2
- DNAJC16 | c.410C>G p.S137* | Nonsense Mutation (SNP) | VAF 72/245 reads (29%) | called by muse, mutect2, varscan2
- DNAJC3 | c.361C>G p.L121V | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- DNAJC6 | c.1326G>C p.E442D | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by mutect2, varscan2
- DOCK1 | c.3835del p.E1279Kfs*22 | Frame Shift Del (DEL) | VAF 24/110 reads (22%) | called by pindel, varscan2
- DOCK11 | c.1515G>T p.T505= | Splice Region (SNP) | VAF 40/114 reads (35%) | called by muse, mutect2, varscan2
- DOCK9 | c.4112C>A p.S1371Y (on ENST00000376460 / NM_001366676.2; = p.S1372Y on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- DPP4 | c.1934G>C p.G645A | Missense Mutation (SNP) | VAF 67/429 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- DPYSL2 | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 40/210 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- DPYSL2 | c.695A>T p.E232V | Missense Mutation (SNP) | VAF 42/219 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- DSC1 | c.601G>T p.D201Y | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DSCAM | c.1167G>T p.K389N | Missense Mutation (SNP) | VAF 41/232 reads (18%) | SIFT tolerated (0.67); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DSP | c.2688G>T p.Q896H | Missense Mutation (SNP) | VAF 119/327 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DSP | c.7817G>T p.S2606I | Missense Mutation (SNP) | VAF 149/406 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- DZIP1 | c.247del p.A83Lfs*5 | Frame Shift Del (DEL) | VAF 47/242 reads (19%) | called by mutect2, pindel, varscan2
- E4F1 | c.76G>C p.G26R | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- E4F1 | c.1903G>T p.V635L | Missense Mutation (SNP) | VAF 32/216 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- EDA2R | c.845C>G p.T282S | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- EFNA5 | c.418+1G>T p.X140_splice | Splice Site (SNP) | VAF 42/151 reads (28%) | called by muse, mutect2, varscan2
- EIF3M | c.76G>T p.G26* | Nonsense Mutation (SNP) | VAF 13/127 reads (10%) | called by muse, mutect2
- EMILIN3 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- EML5 | c.760G>T p.G254C | Missense Mutation (SNP) | VAF 50/264 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ENOX1 | c.662C>A p.A221D | Missense Mutation (SNP) | VAF 51/313 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ENTPD5 | c.614C>A p.T205N | Missense Mutation (SNP) | VAF 38/263 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPB41L3 | c.359C>A p.S120* | Nonsense Mutation (SNP) | VAF 55/202 reads (27%) | called by muse, mutect2, varscan2
- EPHA3 | c.391C>G p.H131D | Missense Mutation (SNP) | VAF 44/239 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- EPHA6 | c.1526T>A p.I509K | Missense Mutation (SNP) | VAF 44/295 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- EPS8L1 | c.672G>C p.Q224H (on ENST00000201647 / NM_133180.3; = p.Q97H on NM_017729.3) | Missense Mutation (SNP) | VAF 34/244 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ERC2 | c.778G>T p.E260* | Nonsense Mutation (SNP) | VAF 53/259 reads (20%) | called by muse, mutect2, varscan2
- ERICH3 | c.3373G>T p.D1125Y | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); called by muse, varscan2
- EXOSC7 | c.784G>T p.V262L | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- EXPH5 | c.1474G>T p.D492Y | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- EYA1 | c.575C>A p.S192* | Nonsense Mutation (SNP) | VAF 19/174 reads (11%) | called by muse, mutect2, varscan2
- EYS | c.6920G>T p.G2307V | Missense Mutation (SNP) | VAF 146/656 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAM133A | c.310T>A p.S104T | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- FAM13C | c.119+1G>T p.X40_splice | Splice Site (SNP) | VAF 52/235 reads (22%) | called by muse, mutect2, varscan2
- FAM155B | c.877T>A p.W293R | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- FAM199X | c.727C>T p.Q243* | Nonsense Mutation (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2, varscan2
- FAM227A | c.1241G>T p.S414I | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- FAM47A | c.1061C>A p.P354H | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM83B | c.1934A>C p.N645T | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- FANCM | c.2003G>T p.G668V | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.026); called by muse, varscan2
- FASTKD5 | c.313G>T p.D105Y | Missense Mutation (SNP) | VAF 40/295 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- FBXL13 | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 67/260 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBXL7 | c.630C>A p.C210* | Nonsense Mutation (SNP) | VAF 109/845 reads (13%) | called by muse, mutect2, varscan2
- FCGBP | c.2921A>T p.D974V | Missense Mutation (SNP) | VAF 30/314 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); called by muse, mutect2
- FCHO1 | c.2132G>T p.W711L | Missense Mutation (SNP) | VAF 53/182 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FCRL6 | c.313G>C p.V105L | Missense Mutation (SNP) | VAF 47/195 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- FGD5 | c.1627G>T p.A543S | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- FGD6 | c.2264A>T p.E755V | Missense Mutation (SNP) | VAF 49/372 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- FGF4 | c.165G>T p.L55F | Missense Mutation (SNP) | VAF 48/219 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- FLII | c.771G>T p.Q257H | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- FLNB | c.4642G>T p.G1548W | Missense Mutation (SNP) | VAF 39/186 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- FLVCR1 | c.1295G>T p.G432V | Missense Mutation (SNP) | VAF 71/270 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- FMN1 | c.3390G>T p.E1130D (on ENST00000616417 / NM_001277313.2; = p.E907D on NM_001103184.4) | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- FMN1 | c.491G>T p.G164V | Missense Mutation (SNP) | VAF 53/173 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- FMN2 | c.624G>T p.Q208H | Missense Mutation (SNP) | VAF 26/218 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.36); called by muse, varscan2
- FMN2 | c.3921-1G>T p.X1307_splice | Splice Site (SNP) | VAF 14/128 reads (11%) | called by muse, varscan2
- FOXE1 | c.892G>T p.A298S | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.121); called by muse, varscan2
- FOXH1 | c.268T>A p.C90S | Missense Mutation (SNP) | VAF 95/519 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- FOXL2 | c.724del p.A242Pfs*29 | Frame Shift Del (DEL) | VAF 8/56 reads (14%) | called by mutect2, pindel, varscan2
- FOXP4 | c.973A>T p.I325F (on ENST00000307972 / NM_001012426.1; = p.I324F on NM_138457.3) | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- FRMD4B | c.2465G>T p.G822V | Missense Mutation (SNP) | VAF 29/339 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2
- FRMPD2 | c.3410G>T p.G1137V | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- FSIP2 | c.311A>T p.H104L | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- FSIP2 | c.1049G>T p.G350V | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.393); called by muse, varscan2
- FSIP2 | c.5761G>T p.V1921L | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- FSIP2 | c.15205C>T p.Q5069* | Nonsense Mutation (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2
- FSIP2 | c.17639C>A p.S5880Y | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- FTCD | c.1236C>A p.D412E | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- FUT11 | c.215C>A p.A72E | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.82); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GABRA1 | c.151G>T p.D51Y | Missense Mutation (SNP) | VAF 82/304 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- GABRG2 | c.1160T>G p.F387C (on ENST00000361925 / NM_001375343.1; = p.F347C on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/616 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GALP | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 19/273 reads (7%) | called by muse, mutect2
- GARNL3 | c.100A>T p.T34S | Missense Mutation (SNP) | VAF 41/313 reads (13%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- GARNL3 | c.1052G>T p.S351I | Missense Mutation (SNP) | VAF 39/278 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GAS1 | c.649G>T p.A217S | Missense Mutation (SNP) | VAF 79/453 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- GAS1 | c.56G>T p.G19V | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- GBP6 | c.1072G>C p.A358P | Missense Mutation (SNP) | VAF 29/202 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- GCAT | c.409G>C p.A137P | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GCAT | c.1066G>T p.A356S | Missense Mutation (SNP) | VAF 28/263 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- GDF6 | c.1337A>T p.D446V | Missense Mutation (SNP) | VAF 48/221 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- GH2 | c.456+1del p.X152_splice | Splice Site (DEL) | VAF 94/431 reads (22%) | called by mutect2, pindel, varscan2
- GK2 | c.155G>T p.W52L | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLP1R | c.743G>T p.G248V | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GLP2R | c.946G>C p.V316L | Missense Mutation (SNP) | VAF 45/210 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- GLT1D1 | c.334G>T p.A112S | Missense Mutation (SNP) | VAF 23/212 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- GNA13 | c.217G>T p.G73W | Missense Mutation (SNP) | VAF 124/455 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- GNAT3 | c.836C>A p.T279N | Missense Mutation (SNP) | VAF 56/207 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, varscan2
- GOLGA4 | c.4364A>T p.Q1455L | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GOLGA8Q | c.1693C>A p.Q565K | Missense Mutation (SNP) | VAF 79/286 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- GOLT1A | c.246G>T p.W82C | Missense Mutation (SNP) | VAF 60/208 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- GPAM | c.1396G>T p.A466S | Missense Mutation (SNP) | VAF 77/361 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPATCH2L | c.1277G>T p.S426I | Missense Mutation (SNP) | VAF 28/330 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.144); called by muse, mutect2
- GPR148 | c.130del p.V44Cfs*29 | Frame Shift Del (DEL) | VAF 18/78 reads (23%) | called by mutect2, pindel, varscan2
- GPR156 | c.234-2A>T p.X78_splice | Splice Site (SNP) | VAF 57/230 reads (25%) | called by muse, mutect2, varscan2
- GPR158 | c.2499C>G p.S833R | Missense Mutation (SNP) | VAF 50/205 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.062); called by muse, varscan2
- GPR85 | c.701G>T p.G234V | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- GPRC5C | c.1094G>T p.R365L (on ENST00000652232; = p.R320L on NM_018653.4) | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- GREB1L | c.4609G>T p.A1537S | Missense Mutation (SNP) | VAF 137/442 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRIK1 | c.1949T>A p.I650K | Missense Mutation (SNP) | VAF 31/160 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GRIK3 | c.2581A>T p.T861S | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GRIN3A | c.2279A>T p.Y760F | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRM1 | c.2525C>T p.P842L | Missense Mutation (SNP) | VAF 58/179 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRM7 | c.893C>A p.A298E | Missense Mutation (SNP) | VAF 55/281 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- GTF3C1 | c.4002-1G>T p.X1334_splice | Splice Site (SNP) | VAF 38/196 reads (19%) | called by muse, mutect2, varscan2
- GUCY1A2 | c.1705G>T p.G569C | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- H2AW | c.181G>T p.A61S | Missense Mutation (SNP) | VAF 82/302 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
1,247 further variants in this file (621 protein-altering or splice-affecting, 385 silent, 241 other) are not listed here.
